Somatic mutation profile of tumor specimen HCM-CSHL-0261-C50-01A (aliquot HCM-CSHL-0261-C50-01A-11D-A85K-36) from HCMI case HCM-CSHL-0261-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: GX; Age at diagnosis: 53.0 years (19,345 days).
Specimen HCM-CSHL-0261-C50-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da7dddfc-1330-4118-9aa2-d8710ad473e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0261-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0261-C50-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2564c6a3-ba7f-4e08-a574-668c7fb922c0

The open-access MAF lists 37 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 9, In Frame Del 1, Frame Shift Del 1, 5'UTR 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 68/285 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 36/141 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATP10B | c.1197C>A p.S399R | Missense Mutation (SNP) | VAF 38/366 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV58778182; called by muse, mutect2, varscan2
- B3GAT1 | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 49/413 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1290128015, COSV100437912; called by muse, mutect2, varscan2
- DDI1 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 92/392 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs770274476, COSV56381028; called by muse, mutect2, varscan2
- GRID1 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 80/488 reads (16%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.947); catalogued as rs150264113; called by muse, varscan2
- HRH2 | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 93/404 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV51576314; called by muse, mutect2, varscan2
- IGKV1-5 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 94/462 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs764059454; called by muse, varscan2
- OR52A1 | c.524C>A p.T175K | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.068); catalogued as rs575135458; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3094C>T p.R1032C | Missense Mutation (SNP) | VAF 52/265 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs777414532, COSV62784355; called by muse, mutect2, varscan2
- REM1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 162/625 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV52428766; called by muse, mutect2, varscan2
- RSPH1 | c.572T>C p.M191T | Missense Mutation (SNP) | VAF 70/299 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs914516787; called by muse, mutect2, varscan2
- SEMA5A | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 32/299 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs145947305; called by muse, mutect2, varscan2
- SH3TC1 | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 129/451 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs552621094, COSV55284475; called by muse, mutect2, varscan2
- TARBP1 | c.4675G>C p.E1559Q | Missense Mutation (SNP) | VAF 62/275 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50212981; called by muse, mutect2, varscan2
- ZNF337 | c.906C>G p.N302K | Missense Mutation (SNP) | VAF 54/532 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.174); catalogued as COSV53321888; called by muse, mutect2
- ALPI | c.1549G>A p.G517R | Missense Mutation (SNP) | VAF 18/417 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- ANKRD11 | c.3853G>T p.E1285* | Nonsense Mutation (SNP) | VAF 93/305 reads (30%) | called by muse, mutect2, varscan2
- CILP2 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 144/554 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- DCTN1 | c.19C>T p.H7Y | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.092); called by muse, mutect2
- IFT80 | c.1346A>T p.K449M | Missense Mutation (SNP) | VAF 29/318 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KIT | c.2349del p.A784Pfs*30 | Frame Shift Del (DEL) | VAF 60/266 reads (23%) | called by mutect2, pindel, varscan2
- LAMA1 | c.5762G>A p.R1921K | Missense Mutation (SNP) | VAF 68/329 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOC2L | c.389_391del p.G130del | In Frame Del (DEL) | VAF 41/364 reads (11%) | called by mutect2, pindel, varscan2
- PCDH7 | c.1313T>C p.V438A | Missense Mutation (SNP) | VAF 68/483 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, varscan2
- PCDHB16 | c.1436A>G p.D479G | Missense Mutation (SNP) | VAF 39/422 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAPN6 | c.219G>A p.L73= | Silent (SNP) | VAF 75/463 reads (16%) | called by muse, mutect2, varscan2
- CARD9 | c.600C>G p.L200= | Silent (SNP) | VAF 82/436 reads (19%) | catalogued as rs779198505; called by muse, mutect2, varscan2
- CHD8 | c.2502G>A p.L834= (on ENST00000646647 / NM_001170629.2; = p.L555= on NM_020920.4) | Silent (SNP) | VAF 44/266 reads (17%) | called by muse, mutect2, varscan2
- CWC27 | c.1110G>A p.L370= | Silent (SNP) | VAF 59/239 reads (25%) | catalogued as COSV66884526; called by muse, mutect2, varscan2
- EML4 | c.12C>T p.F4= | Silent (SNP) | VAF 104/533 reads (20%) | catalogued as rs1321827535, COSV59296728; called by muse, mutect2
- FREM3 | c.2874C>T p.D958= | Silent (SNP) | VAF 68/268 reads (25%) | catalogued as rs900565176; called by muse, mutect2, varscan2
- OBSCN | c.22164G>A p.K7388= | Silent (SNP) | VAF 107/543 reads (20%) | catalogued as rs1017657211; called by muse, mutect2, varscan2
- PDZD8 | c.1182C>T p.V394= | Silent (SNP) | VAF 93/446 reads (21%) | called by muse, mutect2, varscan2
- QTRT2 | c.1071G>A p.K357= | Silent (SNP) | VAF 78/346 reads (23%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840364 C>T | 5'Flank (SNP) | VAF 49/581 reads (8%) | catalogued as COSV58330055; called by muse, mutect2
- KCNN2 | c.-334G>A | 5'UTR (SNP) | VAF 24/368 reads (7%) | called by muse, mutect2
